Gene-level copy-number profile of tumor specimen HCM-CSHL-0238-C18-01B from HCMI case HCM-CSHL-0238-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 71.8 years (26,209 days).
Specimen HCM-CSHL-0238-C18-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6799c9c5-69fc-4f67-bad0-ec9a57edcba1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0238-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/3132d9df-e009-4b3b-b8f4-78795734e33e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 513; copy number 2: 38; copy number 3: 7,799; copy number 4: 25,375; copy number 5: 13,460; copy number 6: 5,034; copy number 7: 2,303; copy number 8: 2,560; copy number 9: 1,513; copy number 10: 308; copy number 13: 4; copy number 22: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,873,899–6,874,005, 1 gene (within-gene range 0–6): RNU6-457P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,826 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene, copy number 10: CFHR3.
- chr2:242,175,181–242,175,634, 1 gene, copy number 22: RPL23AP88.
- chr7:69,594,793–70,793,506, 2 genes, copy number 9: CT66, AUTS2.
- chr13:73,191,528–111,305,737, 418 genes, copy number 9 (broad region; genes not listed).
- chr19:1,086,574–1,106,791, 2 genes, copy number 9 (within-gene range 6–9): POLR2E, GPX4.
- chr19:58,573,503–58,605,223, 4 genes, copy number 13 (within-gene range 5–13): CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.
- chr20:87,250–16,053,197, 288 genes, copy number 9–10 (within-gene range 7–10) (broad region; genes not listed).
- chr20:15,280,764–64,327,972, 1,110 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
